Gene-level copy-number profile of tumor specimen TCGA-CI-6620-01A from TCGA case TCGA-CI-6620, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 41.9 years (15,322 days).
Specimen TCGA-CI-6620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.17ebc079-be02-417e-b924-1c7f6aa91665.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CI-6620-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a409034d-2e7a-43be-824b-36eb9a7e9044

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,642; copy number 3: 3,713; copy number 4: 46,564; copy number 5: 776; copy number 6: 1,088; copy number 9: 30; copy number 19: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CI-6620-01A-11D-1825-01): tumor purity 0.45, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 37 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:16,188,485–16,610,594, 7 genes, copy number 19: SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2.
- chr12:29,389,289–31,252,597, 30 genes, copy number 9 (within-gene range 6–9): OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
